Gene-level copy-number profile of tumor specimen C3N-00437-02 from CPTAC case C3N-00437, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 69.8 years (25,495 days).
Specimen C3N-00437-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a3a007c7-8ff0-4dea-8134-277a2bc765a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00437-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/f9048893-6256-4543-a2d0-07a3b1a99163

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 2,330; copy number 3: 1,345; copy number 4: 18,925; copy number 5: 13,652; copy number 6: 10,225; copy number 7: 3,838; copy number 8: 3,566; copy number 10: 2,999; copy number 11: 1,494; copy number 12: 4; copy number 13: 23.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,520 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:767,382–1,386,409, 23 genes, copy number 13: BRD9P2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3.
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 11 (broad region; genes not listed).
- chr10:104,122,058–104,126,385, 1 gene, copy number 12: SFR1.
- chr12:12,310–133,238,549, 2,999 genes, copy number 10 (broad region; genes not listed).
- chr14:73,840,520–73,858,165, 2 genes, copy number 12 (within-gene range 4–12): AC005520.4, Y_RNA.
- chr21:28,013,363–28,023,233, 1 gene, copy number 12: LINC00314.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
